Somatic mutation profile of tumor specimen 0DK96Q from CCDI case PBBRZH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.7 years (1,715 days).
Specimen 0DK96Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6084d4c0-6846-4bbe-bc80-5de73fefe634.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK96B (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1f3e18f-6df6-427e-8962-7db887bb2a85

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 447/938 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC5 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 451/960 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs1321489314; called by muse, mutect2, varscan2
- ADCY2 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 52/1454 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100602107; called by muse, mutect2
- AKT3 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 26/645 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV55608355; called by muse, mutect2
- C16orf71 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 289/617 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767265532, COSV54795183; called by muse, mutect2, varscan2
- CFHR3 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 42/649 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs779855453, COSV66401561; called by muse, mutect2
- DDX3X | c.973C>G p.R325G (on ENST00000399959; = p.R326G on NM_001356.5) | Missense Mutation (SNP) | VAF 524/571 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV67863531; called by muse, mutect2, varscan2
- GLI2 | c.174C>G p.F58L | Missense Mutation (SNP) | VAF 184/491 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV100084064; called by muse, mutect2, varscan2
- HRH1 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 352/776 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRAF6 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 376/952 reads (39%) | called by muse, varscan2
- XRCC6 | c.195+71G>T | Intron (SNP) | VAF 117/243 reads (48%) | called by muse, mutect2, varscan2
